Somatic mutation profile of tumor specimen TCGA-EB-A3Y7-01A (aliquot TCGA-EB-A3Y7-01A-11D-A23B-08) from TCGA case TCGA-EB-A3Y7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 86.6 years (31,622 days).
Specimen TCGA-EB-A3Y7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efaa0aec-7175-4058-9aab-abc935eb3936.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A3Y7-10A (Blood Derived Normal), aliquot TCGA-EB-A3Y7-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa907387-ee9b-480f-9e03-efe3590a6f9c

The open-access MAF lists 1,306 somatic variants for this specimen: 875 protein-altering or splice-affecting, 405 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 801, Silent 405, Nonsense Mutation 43, Splice Site 13, Intron 12, Splice Region 9, RNA 7, Translation Start Site 3, 5'UTR 2, 3'UTR 2, Nonstop Mutation 2, In Frame Del 2.

Variants (750 of 1,306; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL2L12 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 22/71 reads (31%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.796); catalogued as rs1057519880, COSV55862483; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 13/54 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KIT | c.1676T>C p.V559A | Missense Mutation (SNP) | VAF 16/81 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs121913517, CM013551, COSV55386973, COSV55388782, COSV55393324; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, mutect2, varscan2
- MYO9A | c.3898C>T p.P1300S | Missense Mutation (SNP) | VAF 41/138 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.964); catalogued as COSV61847987; called by muse, mutect2, varscan2
- A2M | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59383615; called by muse, mutect2, varscan2
- A2M | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778604418, COSV59383298; called by muse, mutect2, varscan2
- AADAC | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV51758350; called by muse, mutect2, varscan2
- AADACL4 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.235); catalogued as rs543973930, COSV66105910; called by muse, mutect2, varscan2
- AARS2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55113646; called by muse, mutect2, varscan2
- ABCA13 | c.5474G>A p.W1825* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV70026223; called by mutect2, varscan2
- ABCA9 | c.3866G>A p.R1289Q | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs1303063798, COSV60621461; called by muse, mutect2, varscan2
- ABCB11 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs201351924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC12 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as COSV60912122; called by muse, mutect2, varscan2
- ABCC9 | c.3728C>T p.S1243L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751402564, COSV53964356; called by muse, mutect2, varscan2
- ABLIM1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV53301274; called by muse, mutect2, varscan2
- AC100868.1 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV51838911; called by muse, mutect2, varscan2
- AC126283.2 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 19/102 reads (19%) | catalogued as COSV67097984, COSV67099039; called by muse, mutect2, varscan2
- ACACB | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as COSV58129614; called by muse, mutect2, varscan2
- ACAP1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV50134224; called by muse, mutect2, varscan2
- ACO2 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as COSV99347106; called by muse, mutect2, varscan2
- ACOT11 | c.764+1G>A p.X255_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as rs761198115, COSV59346593; called by muse, mutect2, varscan2
- ACOXL | c.1390G>A p.D464N (on ENST00000389811 / NM_001371254.1; = p.D434N on NM_001142807.4) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV67733709; called by muse, mutect2, varscan2
- ACSBG2 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.071); catalogued as COSV53123229; called by muse, varscan2
- ACSL5 | c.1468G>A p.E490K (on ENST00000354273; = p.E546K on NM_016234.3) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.147); catalogued as rs867135949, COSV61129188; called by muse, mutect2, varscan2
- ADAD1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 64/289 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.843); catalogued as COSV56641542; called by muse, mutect2, varscan2
- ADAM2 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.065); catalogued as COSV55859555; called by muse, mutect2, varscan2
- ADAM21 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV50789084; called by muse, mutect2
- ADAM21 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV50789103; called by muse, mutect2, varscan2
- ADAM29 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286023799, COSV63661077; called by muse, mutect2, varscan2
- ADAMDEC1 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV56474387; called by muse, mutect2, varscan2
- ADAMTS10 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.803); catalogued as rs782396164, COSV54352584; ClinVar: uncertain significance; called by mutect2, varscan2
- ADAMTS16 | c.317A>T p.H106L | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV56980624; called by muse, mutect2, varscan2
- ADAMTS9 | c.2981G>A p.G994E | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV55776298; called by muse, mutect2, varscan2
- ADAMTSL4 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.28); catalogued as COSV54997272; called by muse, mutect2, varscan2
- ADARB1 | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV62342432; called by muse, mutect2, varscan2
- ADCY10 | c.4471G>A p.E1491K | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV63238864; called by muse, mutect2, varscan2
- ADCY4 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1283804610, COSV60251875; called by muse, mutect2, varscan2
- ADH1B | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764414006, COSV59295375; called by muse, mutect2, varscan2
- ADH1C | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV72463392; called by muse, mutect2, varscan2
- ADORA2B | c.982C>T p.L328F | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV58481512; called by muse, mutect2, varscan2
- AFF1 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57117552; called by muse, mutect2, varscan2
- AGPS | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51561544; called by muse, mutect2, varscan2
- AGTR1 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); catalogued as COSV62557456, COSV62559136; called by muse, mutect2, varscan2
- AHNAK2 | c.9890C>A p.A3297D | Missense Mutation (SNP) | VAF 73/270 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV60909276; called by muse, mutect2, varscan2
- AHNAK2 | c.9395C>A p.A3132D | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV60909282; called by muse, mutect2, varscan2
- AIF1 | c.418A>G p.K140E | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.236); catalogued as COSV61962210; called by muse, mutect2, varscan2
- AIPL1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs549595673, COSV51506031; called by mutect2, varscan2
- AKAP9 | c.11066C>T p.S3689F (on ENST00000359028; = p.S3665F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62340221; called by muse, mutect2, varscan2
- AKR1D1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1268160999, COSV54336420, COSV54338239; called by muse, mutect2, varscan2
- AKR1D1 | c.930A>T p.E310D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV54336432; called by muse, mutect2, varscan2
- AKR1E2 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1339066082, COSV53629729; called by muse, mutect2, varscan2
- ALCAM | c.1610T>C p.L537P | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60245927; called by muse, mutect2, varscan2
- ALDH16A1 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV53192928; called by muse, mutect2, varscan2
- ALDH1A2 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51078565, COSV99990651; called by muse, mutect2, varscan2
- ALDH1L2 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV51553622; called by muse, mutect2, varscan2
- ALPK2 | c.4007C>T p.P1336L | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs751297725, COSV64490763; called by muse, mutect2, varscan2
- AMT | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV56469000; called by muse, mutect2, varscan2
- AMTN | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV59488508; called by muse, mutect2, varscan2
- ANAPC2 | c.1367T>C p.L456P | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60568730; called by muse, mutect2, varscan2
- ANGPT1 | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1240911033, COSV52432708; called by muse, mutect2, varscan2
- ANK1 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV55875116; called by muse, mutect2, varscan2
- ANK1 | c.118A>G p.K40E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.327); catalogued as rs921607994, COSV55875131; called by muse, mutect2, varscan2
- ANK3 | c.7003G>A p.E2335K | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs769392075, COSV55047176; called by muse, mutect2, varscan2
- ANK3 | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55042481, COSV55047189; called by muse, mutect2
- ANKEF1 | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101000994; called by muse, mutect2, varscan2
- ANKEF1 | c.1643+1G>A p.X548_splice | Splice Site (SNP) | VAF 15/56 reads (27%) | catalogued as COSV65692408, COSV65692455; called by muse, mutect2, varscan2
- ANKRD42 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52614638; called by muse, mutect2, varscan2
- ANXA9 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs775255778, COSV64484258; called by muse, mutect2, varscan2
- AOX1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV65980466; called by muse, mutect2, varscan2
- AP3B2 | c.2731G>A p.G911S (on ENST00000261722; = p.G905S on NM_004644.5) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.144); catalogued as COSV55607006; called by muse, mutect2, varscan2
- APBB1IP | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV66130834; called by muse, mutect2, varscan2
- APOB | c.12436G>A p.D4146N | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs778195760, COSV51925865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.5419G>A p.D1807N | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.774); catalogued as rs763043332, COSV51925891; called by muse, mutect2, varscan2
- APOB | c.5247G>A p.M1749I | Missense Mutation (SNP) | VAF 72/241 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV51925904; called by muse, mutect2, varscan2
- AQR | c.2780A>G p.Y927C | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1360856681, COSV50030020; called by muse, mutect2, varscan2
- ARG1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV51580658; called by muse, mutect2
- ARHGAP31 | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV51789813; called by muse, mutect2, varscan2
- ARHGEF4 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 52/174 reads (30%) | catalogued as COSV58118643; called by muse, mutect2, varscan2
- ARID5B | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as rs537465187, COSV54415273; called by muse, mutect2, varscan2
- ARID5B | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV54415290; called by muse, mutect2, varscan2
- ARMC10 | c.1007T>G p.V336G | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV58521412; called by muse, mutect2, varscan2
- ARNTL2 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as rs1264881724, COSV53824090; called by muse, mutect2, varscan2
- ASIC5 | c.586-1G>A p.X196_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | catalogued as COSV72232542; called by muse, mutect2, varscan2
- ASTN1 | c.3296T>G p.V1099G | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.698); catalogued as COSV62492544; called by muse, mutect2, varscan2
- ATCAY | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV56654640; called by muse, mutect2, varscan2
- ATL1 | c.528T>G p.Y176* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV63296021; called by muse, mutect2, varscan2
- ATP9B | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs952837369, COSV56947200; called by muse, mutect2, varscan2
- ATXN2L | c.1907dup p.V637Gfs*11 | Frame Shift Ins (INS) | VAF 18/108 reads (17%) | catalogued as rs770460809; called by mutect2, pindel, varscan2
- B3GAT1 | c.491C>G p.P164R | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV56995432, COSV56996502; called by muse, mutect2
- BACH2 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV57585885; called by muse, mutect2, varscan2
- BANP | c.1063C>T p.P355S (on ENST00000286122; = p.P324S on NM_017869.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.113); catalogued as rs775192445, COSV53734511; called by muse, mutect2, varscan2
- BAZ2A | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as rs200871378, COSV51632763; called by muse, mutect2, varscan2
- BCAS3 | c.2372+1G>A p.X791_splice (on ENST00000390652 / NM_001353144.2; = p.X776_splice on NM_017679.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV66770671; called by muse, mutect2, varscan2
- BEND2 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV66215225; called by muse, mutect2, varscan2
- BICRAL | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58403826; called by muse, mutect2, varscan2
- BIRC6 | c.13975C>T p.L4659F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70196229; called by muse, mutect2, varscan2
- BLK | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52049935; called by muse, mutect2, varscan2
- BMP10 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.453); catalogued as COSV54894285; called by muse, mutect2, varscan2
- BMPR2 | c.1757C>A p.S586* | Nonsense Mutation (SNP) | VAF 24/93 reads (26%) | catalogued as COSV65807794; called by muse, mutect2, varscan2
- BNC1 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV61756686; called by muse, mutect2, varscan2
- BNC2 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.14); catalogued as COSV66141718; called by muse, mutect2, varscan2
- BRPF1 | c.1909C>T p.L637F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1034031035, COSV57403476; called by muse, mutect2, varscan2
- BTBD11 | c.2065G>A p.E689K (on ENST00000280758 / NM_001018072.2; = p.E226K on NM_001017523.2) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs866460279, COSV55018468; called by muse, mutect2, varscan2
- BTBD7 | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs201183090, COSV58283992; called by muse, mutect2, varscan2
- BTNL3 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61564523; called by muse, mutect2, varscan2
- C1orf105 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV51129632; called by muse, mutect2, varscan2
- C1orf94 | c.1010-1G>A p.X337_splice (on ENST00000488417 / NM_001134734.2; = p.X147_splice on NM_032884.5) | Splice Site (SNP) | VAF 31/98 reads (32%) | catalogued as rs1206237005, COSV64913199; called by muse, mutect2, varscan2
- C4A | c.3239C>T p.A1080V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101418314; called by muse, mutect2, varscan2
- C6 | c.2273C>G p.S758C | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV54706420; called by muse, mutect2, varscan2
- C7 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs977493333, COSV57471713; called by muse, mutect2, varscan2
- C8orf34 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs149687512, COSV57398509; called by muse, mutect2, varscan2
- CA11 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50032771; called by muse, mutect2, varscan2
- CACNA1A | c.1858C>T p.L620F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64191618; called by muse, mutect2, varscan2
- CAPN11 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV101291816, COSV67236383; called by muse, mutect2, varscan2
- CAPN13 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99699889, COSV99701133; called by muse, mutect2, varscan2
- CAPZA2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV63266034; called by muse, mutect2, varscan2
- CARMIL3 | c.145T>C p.S49P | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV57725291; called by muse, varscan2
- CASQ2 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54768066; called by muse, mutect2, varscan2
- CBL | c.1258C>G p.R420G | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1314298, COSV50630874, COSV50653789; called by muse, mutect2, varscan2
- CBLC | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.739); catalogued as COSV54321638; called by muse, mutect2, varscan2
- CBLL2 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.348); catalogued as COSV60368523; called by muse, mutect2, varscan2
- CBX2 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs991763070; called by muse, mutect2
- CCDC144A | c.861G>A p.W287* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as rs766556877, COSV60696768; called by muse, mutect2, varscan2
- CCDC144A | c.2777A>C p.D926A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV60696784; called by muse, mutect2, varscan2
- CCDC54 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53758113, COSV53759291; called by muse, mutect2, varscan2
- CCDC9 | c.4-1G>A p.X2_splice | Splice Site (SNP) | VAF 35/114 reads (31%) | catalogued as COSV55719818; called by muse, mutect2, varscan2
- CCL23 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs746038053; called by muse, mutect2
- CD163 | c.2495G>A p.R832K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV63130140, COSV63133692; called by muse, mutect2, varscan2
- CD163L1 | c.3950G>A p.G1317E | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867081460, COSV58011299; called by muse, mutect2, varscan2
- CD22 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as COSV99322944; called by muse, mutect2, varscan2
- CD300A | c.488A>T p.H163L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV60409610; called by muse, mutect2, varscan2
- CD300C | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs758092230, COSV58169755; called by muse, mutect2, varscan2
- CD33 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.631); catalogued as COSV51800256; called by muse, mutect2, varscan2
- CD86 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV52605405; called by muse, mutect2, varscan2
- CD96 | c.1682C>T p.P561L (on ENST00000283285 / NM_198196.3; = p.P545L on NM_005816.5) | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51913436; called by muse, mutect2, varscan2
- CDH19 | c.1327A>G p.T443A | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.527); catalogued as COSV50954991; called by muse, mutect2, varscan2
- CDH26 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV54843647; called by muse, mutect2, varscan2
- CDH6 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs202247793, COSV54065357; called by muse, mutect2, varscan2
- CDH8 | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV54852039, COSV54868465; called by muse, mutect2, varscan2
- CDK12 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs767506835, COSV70999544; called by muse, mutect2, varscan2
- CDK17 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54127100; called by muse, mutect2, varscan2
- CDX4 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV65171487; called by muse, mutect2, varscan2
- CEACAM1 | c.541A>T p.N181Y | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50725723; called by muse, mutect2, varscan2
- CELSR2 | c.7117A>G p.I2373V | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV54767876; called by muse, mutect2, varscan2
- CFAP44 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV55609286; called by muse, mutect2, varscan2
- CFAP54 | c.5806G>A p.A1936T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as COSV61570956; called by muse, mutect2, varscan2
- CFH | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as COSV66406370; called by muse, mutect2, varscan2
- CFH | c.2224C>T p.P742S | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1313104462, COSV66406376; called by muse, mutect2, varscan2
- CFHR2 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780291426, COSV66380613; called by muse, mutect2, varscan2
- CHMP2B | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55461386; called by muse, mutect2, varscan2
- CLCA4 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55366718; called by muse, mutect2, varscan2
- CLDN17 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV54522385; called by muse, mutect2, varscan2
- CLIP3 | c.476G>A p.W159* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV62111851; called by muse, mutect2
- CMKLR1 | c.646C>T p.R216W (on ENST00000312143 / NM_001142344.2; = p.R214W on NM_004072.3) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs768395188, COSV56436147; called by muse, mutect2, varscan2
- CMYA5 | c.2711C>T p.S904L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV71404314, COSV71408505; called by muse, mutect2, varscan2
- CNGA3 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs566717145, COSV55622760; called by muse, mutect2, varscan2
- CNKSR1 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64162920; called by muse, mutect2, varscan2
- CNTN3 | c.2693C>T p.T898I | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1189079760, COSV55164728; called by muse, mutect2, varscan2
- COL11A2 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.689); catalogued as rs970615748, COSV59494221; called by muse, mutect2, varscan2
- COL15A1 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1035808629, COSV66641817; called by muse, mutect2, varscan2
- COL15A1 | c.3688G>A p.D1230N | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV66641823; called by muse, mutect2, varscan2
- COL4A4 | c.4247G>A p.R1416K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs370734150, COSV61629403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.3466C>T p.P1156S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs191227240, COSV66407663; called by muse, mutect2, varscan2
- COL6A5 | c.6838C>T p.P2280S (on ENST00000312481; = p.P2276S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV55194824; called by muse, mutect2
- COLEC10 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60520707; called by muse, mutect2, varscan2
- CORIN | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV56687522; called by muse, mutect2, varscan2
- CORIN | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as COSV56687533; called by muse, mutect2, varscan2
- CORO1C | c.392A>C p.K131T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99775785; called by muse, mutect2, varscan2
- CPA4 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99744736; called by muse, mutect2, varscan2
- CPED1 | c.2896T>G p.Y966D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV59998138; called by muse, mutect2, varscan2
- CRISP3 | c.283G>A p.E95K (on ENST00000371159 / NM_001368123.1; = p.E77K on NM_006061.4) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs867301738, COSV53819285; called by muse, mutect2, varscan2
- CSMD2 | c.7723G>A p.D2575N | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.284); catalogued as COSV53886092; called by muse, mutect2, varscan2
- CSMD2 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.497); catalogued as rs759845804, COSV53886118; called by muse, mutect2, varscan2
- CSMD3 | c.7811G>A p.G2604E (on ENST00000297405 / NM_001363185.1; = p.G2500E on NM_052900.3) | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52116848; called by muse, mutect2, varscan2
- CSNK1A1 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55793251; called by muse, mutect2, varscan2
- CSPG4 | c.2249A>T p.H750L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100413554; called by muse, mutect2, varscan2
- CUZD1 | c.1766T>G p.V589G | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV59025811; called by muse, mutect2, varscan2
- CWC22 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV55427145; called by muse, mutect2
- CYLC1 | c.1828C>T p.P610S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.796); catalogued as COSV61410428; called by muse, mutect2, varscan2
- CYP2C8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359014715, COSV64876146; called by muse, mutect2, varscan2
- CYP2C9 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV53247075; called by muse, mutect2, varscan2
- CYP3A43 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV55935250; called by muse, mutect2
- CYP4F11 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV56125895; called by muse, mutect2, varscan2
- DCAF4L2 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs766389714, COSV100151126, COSV60476878; called by muse, mutect2, varscan2
- DCX | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57566503; called by muse, mutect2, varscan2
- DDAH2 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV65383671; called by muse, mutect2, varscan2
- DDB1 | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs1219853323, COSV57101363; called by muse, mutect2, varscan2
- DDX10 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs188412255, COSV59438952; called by muse, mutect2, varscan2
- DDX60L | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52709950; called by muse, mutect2
- DENND3 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as rs1219509726, COSV52801170; called by muse, varscan2
- DGLUCY | c.1615C>T p.H539Y | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99824103; called by muse, varscan2
- DGLUCY | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.031); catalogued as COSV99824107; called by muse, varscan2
- DHRS7C | c.825G>T p.M275I (on ENST00000330255 / NM_001220493.2; = p.M274I on NM_001105571.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV57649838; called by muse, mutect2, varscan2
- DIP2C | c.3887C>T p.S1296L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV55148602; called by muse, mutect2, varscan2
- DMBT1 | c.7414C>T p.R2472W (on ENST00000338354 / NM_001377530.1; = p.R1715W on NM_004406.3) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs867500352, COSV57533469; called by muse, mutect2, varscan2
- DNAH11 | c.7238C>T p.A2413V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV60943253; called by muse, mutect2, varscan2
- DNAH17 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs866018949, COSV67750444; called by muse, mutect2, varscan2
- DNAH2 | c.6427G>A p.D2143N | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66717252; called by muse, mutect2, varscan2
- DNAH3 | c.2521T>C p.L841= | Splice Region (SNP) | VAF 24/77 reads (31%) | catalogued as COSV54507280; called by muse, mutect2, varscan2
- DNAH7 | c.5962-1G>A p.X1988_splice | Splice Site (SNP) | VAF 7/23 reads (30%) | catalogued as COSV56754445; called by muse, mutect2, varscan2
- DNAH9 | c.8093A>G p.K2698R | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV52337797; called by muse, mutect2, varscan2
- DNAJB5 | c.223G>C p.G75R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV56624578, COSV56624822; called by muse, mutect2, varscan2
- DNAJC6 | c.1177T>G p.S393A | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV54770742; called by muse, mutect2, varscan2
- DNMBP | c.2922C>T p.V974= | Splice Region (SNP) | VAF 25/112 reads (22%) | catalogued as COSV60621530; called by muse, mutect2, varscan2
- DNMT1 | c.3671C>T p.P1224L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV61576995; called by muse, mutect2, varscan2
- DOCK3 | c.4958C>T p.S1653F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as COSV56506803; called by muse, mutect2, varscan2
- DPPA3 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs753598013, COSV61503931; called by muse, mutect2, varscan2
- DPPA3 | c.369G>A p.K123= | Splice Region (SNP) | VAF 6/21 reads (29%) | catalogued as COSV61502805; called by muse, mutect2, varscan2
- DPPA4 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59509498, COSV59511688; called by muse, mutect2, varscan2
- DPPA4 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV59509507; called by muse, mutect2, varscan2
- DPYSL5 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV56509456; called by muse, mutect2, varscan2
- DSC1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV57142623; called by muse, mutect2, varscan2
- DSCAM | c.4630T>A p.Y1544N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101259353; called by muse, varscan2
- DSCAM | c.4573C>T p.Q1525* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV68022092; called by muse, varscan2
- DTX3 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV54084829; called by muse, mutect2, varscan2
- DUSP4 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.347); catalogued as COSV53545014; called by muse, mutect2, varscan2
- DYNC1H1 | c.10537T>C p.F3513L | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV64134821; called by muse, mutect2, varscan2
- EDC4 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.133); catalogued as COSV54645324; called by muse, mutect2, varscan2
- EDDM3B | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as rs751569950, COSV58746721, COSV58747520; called by muse, mutect2, varscan2
- EFCAB3 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV59500178; called by muse, mutect2, varscan2
- EFNA3 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1166777002, COSV100860804; called by muse, mutect2
- EFNA3 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100860805; called by muse, mutect2
- EIF5AL1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV73122932; called by muse, mutect2, varscan2
- ELAC2 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.581); catalogued as rs1211428067, COSV52389935; called by muse, mutect2, varscan2
- EMILIN3 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.549); catalogued as rs771775276, COSV60035299; called by muse, mutect2, varscan2
- ENAM | c.3226G>A p.D1076N | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs140345705, COSV68535392; called by muse, mutect2, varscan2
- ENPP2 | c.1180C>T p.R394* (on ENST00000075322 / NM_001040092.3; = p.R446* on NM_006209.5) | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV50010426; called by muse, mutect2, varscan2
- ENPP4 | c.686A>G p.N229S | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV58088392; called by muse, mutect2, varscan2
- ENTR1 | c.1244T>C p.V415A (on ENST00000357365 / NM_001039707.2; = p.V392A on NM_006643.4) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs765352352, COSV53731215; called by mutect2, varscan2
- EPHA6 | c.2107C>T p.P703S (on ENST00000389672 / NM_001080448.3; = p.P95S on NM_173655.4) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67561756; called by muse, mutect2, varscan2
- EPHB3 | c.2858C>T p.S953F | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV57804581; called by muse, mutect2, varscan2
- ERAP2 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.798); catalogued as rs199510383; called by muse, mutect2, varscan2
- ERAP2 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65938914; called by muse, mutect2, varscan2
- ESRP1 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64408200; called by muse, mutect2, varscan2
- EVC2 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs145758016, COSV60388597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVL | c.359C>T p.S120F (on ENST00000402714 / NM_001330221.2; = p.S122F on NM_016337.3) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV67374463; called by muse, mutect2
- EXD2 | c.1451C>T p.P484L (on ENST00000312994 / NM_001193362.1; = p.P359L on NM_018199.3) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57278395; called by muse, mutect2
- EXPH5 | c.5180G>A p.R1727K | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as rs778865772, COSV56199488; called by muse, mutect2, varscan2
- F5 | c.4957G>A p.D1653N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); catalogued as COSV63121401; called by muse, mutect2, varscan2
- FAAH | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV54543253; called by muse, mutect2, varscan2
- FAM133A | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.418); catalogued as COSV59074039; called by muse, mutect2, varscan2
- FAM135B | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 47/133 reads (35%) | catalogued as COSV52709409, COSV52726334; called by muse, mutect2, varscan2
- FAM170A | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs866408375, COSV58924222; called by muse, mutect2, varscan2
- FAM171A1 | c.2605G>A p.G869R | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65313899; called by muse, mutect2, varscan2
- FAM71B | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57227834; called by muse, mutect2, varscan2
- FAM71C | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV60942684, COSV60943367; called by muse, mutect2, varscan2
- FAM81A | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as rs760859301, COSV55676532; called by muse, mutect2, varscan2
- FAM81A | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV55676542, COSV99893441; called by muse, mutect2, varscan2
- FAT4 | c.6601G>A p.E2201K | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs866400807, COSV58674112; called by muse, mutect2
- FBN2 | c.3241C>T p.P1081S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.138); catalogued as rs863223601, COSV52496687; called by muse, mutect2, varscan2
- FBN2 | c.1537A>T p.T513S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV52496714; called by muse, mutect2, varscan2
- FCER1A | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV100929295, COSV63666650; called by muse, mutect2, varscan2
- FCRL3 | c.1410A>C p.T470= | Splice Region (SNP) | VAF 54/274 reads (20%) | catalogued as COSV63839915; called by muse, mutect2, varscan2
- FER1L6 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217685259, COSV67548427; called by muse, mutect2, varscan2
- FGD6 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as rs751217978, COSV59690883; called by muse, mutect2, varscan2
- FHDC1 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV52598127; called by muse, mutect2, varscan2
- FILIP1L | c.2627G>A p.G876E (on ENST00000354552 / NM_182909.3; = p.G636E on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1197919343, COSV58765591; called by muse, mutect2, varscan2
- FLG2 | c.4784G>A p.R1595Q | Missense Mutation (SNP) | VAF 178/452 reads (39%) | SIFT tolerated (0.59); catalogued as rs201802558, COSV101165639, COSV66167043; called by muse, mutect2, varscan2
- FMN1 | c.2054G>A p.S685N (on ENST00000616417 / NM_001277313.2; = p.S462N on NM_001103184.4) | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV57918804; called by muse, mutect2
- FMO1 | c.562C>T p.L188F | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs977693406, COSV61444843; called by muse, mutect2, varscan2
- FMOD | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as rs145322178; called by muse, mutect2, varscan2
- FNDC1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.449); catalogued as rs781125048, COSV51932111; called by muse, mutect2, varscan2
- FNDC1 | c.5301G>A p.W1767* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV51932123; called by muse, mutect2, varscan2
- FRAS1 | c.4549G>A p.E1517K | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs774373319, COSV53593978; called by muse, mutect2, varscan2
- FREM1 | c.2839G>A p.D947N | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV101085723, COSV66517749, COSV66518799; called by muse, mutect2, varscan2
- FREM1 | c.2714G>A p.G905E | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs754613342, COSV66518804; called by muse, mutect2, varscan2
- FSIP1 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553692762, COSV63223656; called by muse, mutect2, varscan2
- FSIP2 | c.19082G>A p.R6361K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.954); catalogued as COSV58079790; called by muse, mutect2, varscan2
- G6PC2 | c.219G>A p.W73* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV56371637; called by muse, mutect2, varscan2
- G6PD | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs1379306569, CM980789, COSV63702440; called by muse, mutect2, varscan2
- GAB3 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV65818903; called by muse, mutect2, varscan2
- GCC2 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as COSV59174437, COSV59175394; called by muse, mutect2, varscan2
- GCNT3 | c.795G>A p.W265* | Nonsense Mutation (SNP) | VAF 67/239 reads (28%) | catalogued as COSV68531973; called by muse, mutect2, varscan2
- GDF3 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as rs1243371429, COSV61711927; called by muse, mutect2, varscan2
- GEM | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs751506282, COSV52596782, COSV99891585; called by muse, mutect2, varscan2
- GHR | c.1510G>A p.G504S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100049677, COSV50107118; called by mutect2, varscan2
- GIT2 | c.132T>A p.H44Q | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58078581; called by muse, mutect2, varscan2
- GJA10 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as COSV65354847; called by muse, mutect2, varscan2
- GJB4 | c.684A>T p.E228D | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV58355629; called by mutect2, varscan2
- GLE1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 68/100 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs867034826, COSV59406648; called by muse, mutect2, varscan2
- GLI1 | c.2807T>C p.V936A | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV57358662; called by muse, mutect2
- GLRB | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868460883, COSV52413855, COSV52423095; called by muse, mutect2, varscan2
- GOLGB1 | c.4234T>C p.S1412P | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV61462453; called by muse, mutect2, varscan2
- GPC1 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs372909320; called by muse, mutect2, varscan2
- GPLD1 | c.1707G>A p.W569* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | catalogued as COSV57754750; called by muse, mutect2, varscan2
- GPR20 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV66684010; called by muse, mutect2, varscan2
- GRM3 | c.1096A>T p.K366* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV64468205; called by muse, mutect2, varscan2
- GTPBP10 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as rs1347730316, COSV55986428, COSV55987917; called by muse, mutect2, varscan2
- GTPBP2 | c.1490A>C p.E497A | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV100199867; called by muse, mutect2, varscan2
- GTPBP4 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62550203; called by muse, mutect2, varscan2
- GUCY1A1 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.606); catalogued as rs556601718, COSV56649696; called by muse, mutect2, varscan2
- H1-0 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV50648695; called by muse, mutect2, varscan2
- H2BW1 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54219797, COSV54219962; called by muse, mutect2, varscan2
- HDAC9 | c.2577+4C>T | Splice Region (SNP) | VAF 22/69 reads (32%) | catalogued as rs752796141; called by muse, mutect2, varscan2
- HECTD4 | c.7687C>T p.R2563C | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764496969, COSV66386636; called by muse, mutect2, varscan2
- HENMT1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs760391142, COSV64229959; called by muse, mutect2, varscan2
- HEPH | c.1183C>T p.P395S (on ENST00000343002; = p.P128S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57960111; called by muse, mutect2, varscan2
- HMCN1 | c.7810C>T p.P2604S | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as COSV54881968; called by muse, mutect2, varscan2
- HOXA3 | c.1130A>G p.N377S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.112); catalogued as rs370472758; called by muse, mutect2
- HRH1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199720564, COSV67954946; called by muse, mutect2, varscan2
- HROB | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 98/313 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV55368945; called by muse, mutect2, varscan2
- HS3ST4 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs867965756, COSV58804388; called by muse, mutect2, varscan2
- HS6ST3 | c.1040A>G p.N347S | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.191); catalogued as COSV65003488; called by muse, mutect2, varscan2
- HSF4 | c.1316C>T p.P439L (on ENST00000521374 / NM_001040667.3; = p.P409L on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV50456675; called by muse, mutect2, varscan2
- HSPA12A | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65021044; called by muse, mutect2, varscan2
- HYDIN | c.13837G>A p.G4613R | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66637631; called by muse, mutect2, varscan2
- HYDIN | c.4798G>A p.D1600N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99992186; called by muse, mutect2, varscan2
- HYDIN | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.251); catalogued as rs776354722, COSV55479046; called by muse, mutect2, varscan2
- HYDIN | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55479080; called by muse, mutect2, varscan2
- IDO1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs867417346, COSV53713200, COSV53716046; called by muse, mutect2
- IFNA6 | c.265A>C p.N89H | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.074); catalogued as COSV66506244; called by muse, mutect2, varscan2
- INA | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.456); catalogued as COSV63975686; called by muse, mutect2, varscan2
- INPP5D | c.3080C>T p.S1027F (on ENST00000445964 / NM_001017915.3; = p.S1026F on NM_005541.5) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV64035505; called by muse, mutect2, varscan2
- INTS2 | c.3025C>T p.P1009S | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52151362; called by muse, mutect2, varscan2
- IQGAP2 | c.2353C>T p.R785C | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as rs534842328, COSV57169035; called by muse, mutect2, varscan2
- ITGA2 | c.2772T>A p.N924K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56857000; called by muse, mutect2, varscan2
- ITIH1 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs200000763, COSV56252801; called by muse, mutect2, varscan2
- ITIH5 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.516); catalogued as COSV53660828; called by muse, mutect2, varscan2
- ITK | c.1720G>A p.G574R | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs777096641, COSV70060651; called by muse, mutect2, varscan2
- ITPR1 | c.4508A>C p.Q1503P (on ENST00000354582; = p.Q1488P on NM_002222.7) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56972121; called by muse, mutect2, varscan2
- ITPR3 | c.4334C>T p.T1445I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV65406408; called by muse, mutect2, varscan2
- KAT2B | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as COSV99768997; called by muse, mutect2, varscan2
- KBTBD8 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV55127150; called by muse, mutect2, varscan2
- KCMF1 | c.869A>G p.Q290R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1176888740, COSV69053304; called by muse, mutect2, varscan2
- KCNB2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.226); catalogued as rs778910036, COSV73048799; called by muse, mutect2, varscan2
- KCNC3 | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.175); catalogued as COSV65386843; called by muse, mutect2, varscan2
- KCNH1 | c.2550G>A p.W850* (on ENST00000271751 / NM_172362.3; = p.W823* on NM_002238.4) | Nonsense Mutation (SNP) | VAF 72/152 reads (47%) | catalogued as COSV55071797; called by muse, mutect2, varscan2
- KCNH8 | c.2276G>A p.G759E | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV60457886; called by muse, varscan2
- KCNIP1 | c.578T>C p.M193T (on ENST00000411494 / NM_001034837.3; = p.M182T on NM_014592.4) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV61081047; called by muse, mutect2, varscan2
- KCNJ6 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.943); catalogued as COSV55710366; called by muse, varscan2
- KCNJ6 | c.184A>C p.K62Q | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.824); catalogued as COSV55710377; called by muse, varscan2
- KCNS3 | c.19T>A p.F7I | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58405636; called by muse, mutect2, varscan2
- KDM7A | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV50090269; called by muse, mutect2, varscan2
- KEL | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 117/455 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV62333627; called by muse, mutect2, varscan2
- KIF14 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV66260182; called by muse, mutect2, varscan2
- KIF21B | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778724409, COSV59753298; called by muse, mutect2, varscan2
- KIF2B | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV52127632; called by muse, mutect2, varscan2
- KIF2B | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs1229299890, COSV52127464; called by muse, mutect2, varscan2
- KIF4B | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs565698502, COSV70528170; called by muse, mutect2, varscan2
- KIF4B | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs770712289, COSV70528176; called by muse, mutect2, varscan2
- KIR2DL4 | c.942G>A p.M314I (on ENST00000396284; = p.M240I on NM_001080770.2) | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV58488477; called by muse, varscan2
- KIR3DL3 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.928); catalogued as COSV52545934; called by muse, mutect2, varscan2
- KL | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs1443103087, COSV66308058; called by muse, mutect2, varscan2
- KLF8 | c.235T>C p.F79L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV63847339; called by muse, mutect2
- KLHL14 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.983); catalogued as rs749816647, COSV63831052; called by muse, mutect2, varscan2
- KLHL14 | c.1588G>A p.G530S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100839187, COSV63831058; called by muse, mutect2, varscan2
- KLHL41 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs752597938, COSV52929606; called by muse, mutect2, varscan2
- KLRG2 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV61800456; called by muse, mutect2, varscan2
- KMO | c.683A>G p.N228S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844673; called by mutect2, varscan2
- KMT2D | c.7690A>C p.S2564R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.446); catalogued as COSV56416661; called by muse, mutect2, varscan2
- KMT2D | c.2857C>T p.P953S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV56416677; called by muse, varscan2
- KRT1 | c.591+1G>A p.X197_splice | Splice Site (SNP) | VAF 35/112 reads (31%) | catalogued as rs267607422, CS015045, CS015046, COSV52865381, COSV99358541; ClinVar: not provided; called by muse, mutect2, varscan2
- KRT28 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs200406506, COSV60683823, COSV60684962; called by muse, mutect2, varscan2
- KRT31 | c.242A>T p.N81I | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52433643; called by muse, mutect2, varscan2
- KRT5 | c.1176G>A p.M392I | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs767692987, COSV52859277; called by muse, mutect2, varscan2
- KRTAP10-10 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1412675546, COSV59954031; called by muse, mutect2, varscan2
- KRTAP5-6 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV66289137; called by muse, mutect2, varscan2
- KSR2 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV60368100; called by muse, mutect2, varscan2
- LAIR2 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV56620922; called by muse, mutect2, varscan2
- LAMB3 | c.1679C>T p.T560I | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV61915591; called by muse, mutect2, varscan2
- LARP1B | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99217876; called by muse, mutect2, varscan2
- LARP1B | c.2090C>T p.P697L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773727610, COSV99217880; called by muse, mutect2, varscan2
- LARP6 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100150747; called by muse, mutect2, varscan2
- LDHD | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.039); catalogued as COSV55580192; called by muse, mutect2, varscan2
- LECT2 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV50846764; called by muse, mutect2, varscan2
- LELP1 | c.150A>T p.E50D | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV64202317; called by muse, mutect2, varscan2
- LEMD1 | c.44A>T p.Q15L | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV65671006; called by muse, mutect2, varscan2
- LEPR | c.2929G>A p.E977K | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.385); catalogued as rs771449483, COSV62746011; called by muse, mutect2, varscan2
- LILRA2 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52188978; called by muse, mutect2, varscan2
- LILRA4 | c.1376T>A p.F459Y | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV52490644; called by muse, mutect2, varscan2
- LILRA5 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV56641318; called by muse, varscan2
- LIPH | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV56183018; called by muse, mutect2, varscan2
- LIPK | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV68200722; called by muse, mutect2
- LRP1 | c.11383G>A p.E3795K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs773744975, COSV54503674; called by muse, mutect2
- LRP2 | c.8633C>T p.P2878L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371790481; called by muse, mutect2, varscan2
- LRP2 | c.2321G>A p.G774E | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1374920686, COSV55543623; called by muse, mutect2, varscan2
- LRRC10 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs751473904, COSV64060089; called by muse, mutect2, varscan2
- LRRC37A3 | c.4812C>T p.I1604= | Splice Region (SNP) | VAF 24/110 reads (22%) | catalogued as COSV58534435; called by muse, mutect2, varscan2
- LRRC61 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs751249038, COSV56230906; called by muse, mutect2, varscan2
- LRRK2 | c.3486G>A p.M1162I | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV54146153; called by muse, mutect2, varscan2
- LTBP1 | c.2933C>T p.A978V (on ENST00000404816 / NM_206943.4; = p.A652V on NM_000627.4) | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV63181458; called by muse, mutect2, varscan2
- MACF1 | c.7682C>T p.S2561F | Missense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV57109604; called by muse, mutect2, varscan2
- MAGEA10 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV54883084; called by muse, mutect2, varscan2
- MAN1A2 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV62976563; called by muse, mutect2, varscan2
- MAP3K14 | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs376396491, COSV60922844; called by muse, mutect2, varscan2
- MAP7 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63417617; called by muse, mutect2, varscan2
- MAPK4 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV68541267; called by muse, mutect2, varscan2
- MAPK9 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs866186701, COSV58119285; called by muse, mutect2, varscan2
- MARCHF4 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV56102458; called by muse, mutect2, varscan2
- MARF1 | c.2330C>T p.S777L | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs755224148, COSV60020455; called by muse, mutect2, varscan2
- MAS1 | c.657G>A p.W219* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as rs1171926339, COSV53120637; called by muse, mutect2, varscan2
- MATK | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV59553407; called by muse, mutect2, varscan2
- MATN4 | c.1474C>T p.R492C (on ENST00000372754; = p.R451C on NM_003833.4) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | PolyPhen probably damaging (0.987); catalogued as rs778298691, COSV61350538; called by muse, mutect2, varscan2
- MCF2 | c.2459G>A p.R820K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV58479254; called by muse, mutect2, varscan2
- MCHR2 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as COSV56000323; called by muse, mutect2, varscan2
- MCM3AP | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99386569; called by muse, mutect2, varscan2
- MDN1 | c.4018G>A p.E1340K | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV101021070, COSV65518222; called by muse, mutect2, varscan2
- MEFV | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV54819050, COSV54821779; called by muse, varscan2
- MEGF8 | c.3862C>T p.P1288S (on ENST00000251268 / NM_001271938.2; = p.P1221S on NM_001410.3) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99234863; called by muse, mutect2
- MEGF8 | c.3863C>T p.P1288L (on ENST00000251268 / NM_001271938.2; = p.P1221L on NM_001410.3) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV99234868; called by muse, mutect2
- MINDY2 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV57505714; called by muse, mutect2, varscan2
- MLXIP | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV59834261; called by muse, mutect2, varscan2
- MMP24 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867807473, COSV55768690; called by muse, mutect2, varscan2
- MON2 | c.3308C>T p.S1103L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54803951; called by muse, mutect2, varscan2
- MORC1 | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs377680519, COSV51715467; called by muse, mutect2, varscan2
- MORC4 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs961640852, COSV55239997; called by muse, mutect2, varscan2
- MPG | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1567123202, COSV54737507; called by muse, mutect2
- MPHOSPH10 | c.1750C>T p.Q584* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV54913807; called by muse, mutect2, varscan2
- MPP2 | c.1016G>A p.G339E (on ENST00000461854 / NM_001278372.2; = p.G315E on NM_005374.5) | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs867281597, COSV52233473; called by muse, mutect2, varscan2
- MPP6 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.06); catalogued as COSV56036132; called by muse, mutect2, varscan2
- MROH5 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs774119773, COSV71300598; called by muse, mutect2, varscan2
- MROH5 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs758310948, COSV71300600; called by muse, mutect2, varscan2
- MROH7 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); catalogued as COSV59868764; called by muse, mutect2, varscan2
- MSH6 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs763593669, COSV52286847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTDH | c.966G>A p.W322* | Nonsense Mutation (SNP) | VAF 37/85 reads (44%) | catalogued as COSV60342929; called by muse, mutect2, varscan2
- MTOR | c.6815C>T p.A2272V | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63868985; called by muse, mutect2, varscan2
- MUC16 | c.37100G>A p.R12367K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.003); catalogued as COSV67449834; called by muse, varscan2
- MUC16 | c.29516C>T p.T9839I | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs201654512; called by muse, mutect2, varscan2
- MUC16 | c.23614C>T p.P7872S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.029); catalogued as rs1438509175, COSV67449872; called by muse, mutect2, varscan2
- MUC16 | c.18600G>A p.M6200I | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.682); catalogued as rs745344038, COSV67449885; called by muse, mutect2, varscan2
- MUC16 | c.15346G>A p.E5116K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.041); catalogued as rs866107833, COSV67449897; called by muse, mutect2, varscan2
- MUC16 | c.14050G>A p.G4684R | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as COSV67449908; called by muse, mutect2, varscan2
- MUC16 | c.12074A>T p.D4025V | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.154); catalogued as COSV67449921; called by muse, mutect2
- MUC16 | c.10397C>T p.S3466F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as COSV67449932; called by muse, mutect2, varscan2
- MUC16 | c.4564G>A p.G1522R | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as rs750368701, COSV67449958; called by muse, mutect2, varscan2
- MUC17 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV60281801; called by muse, mutect2, varscan2
- MVP | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62421513; called by muse, mutect2
- MX2 | c.1100T>C p.V367A | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV58095369; called by muse, mutect2, varscan2
- MYBPC3 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as rs397515953, COSV57023942, COSV57028482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH1 | c.5716G>A p.E1906K | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as rs368680249; called by muse, mutect2, varscan2
- MYH1 | c.3722C>T p.T1241I | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV56844608; called by muse, mutect2, varscan2
- MYH13 | c.4984G>A p.D1662N | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1197798249, COSV52822155; called by muse, mutect2
- MYH2 | c.5747C>T p.A1916V | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55432879; called by muse, mutect2, varscan2
- MYO15A | c.4999T>G p.F1667V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52752892; called by muse, mutect2, varscan2
- MYOC | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV50673994; called by muse, mutect2, varscan2
- MYT1 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV60501879; called by muse, mutect2, varscan2
- N4BP2 | c.2036A>G p.E679G | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.747); catalogued as COSV54699711; called by muse, mutect2, varscan2
- NAA11 | c.434A>C p.Y145S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV54514038; called by muse, mutect2, varscan2
- NAB1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61608297; called by muse, mutect2, varscan2
- NAV3 | c.5606C>T p.S1869F (on ENST00000397909 / NM_001024383.2; = p.S1847F on NM_014903.6) | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.982); catalogued as rs1418205857, COSV57065429; called by muse, mutect2, varscan2
- NCAN | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV53047482; called by muse, mutect2, varscan2
- NCK2 | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV51889034; called by muse, mutect2, varscan2
- NCOA6 | c.4436T>A p.L1479* | Nonsense Mutation (SNP) | VAF 33/122 reads (27%) | catalogued as COSV62861769; called by muse, mutect2, varscan2
- NDST3 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56613987; called by muse, mutect2, varscan2
- NDST4 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.192); catalogued as COSV52111031; called by muse, mutect2, varscan2
- NEB | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.087); catalogued as COSV50832537; called by muse, mutect2, varscan2
- NEUROD6 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.283); catalogued as COSV51770324; called by muse, mutect2, varscan2
- NEXMIF | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV50022878; called by muse, mutect2, varscan2
- NF1 | c.3694C>G p.P1232A | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.109); catalogued as CM143387, COSV62195052; called by muse, mutect2, varscan2
- NFKBIZ | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV58199624; called by muse, mutect2, varscan2
- NFYC | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100438304, COSV58126011; called by muse, mutect2, varscan2
- NIBAN1 | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 77/442 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV62283348; called by muse, mutect2, varscan2
- NKD2 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV56890110; called by muse, mutect2, varscan2
- NLGN4X | c.1572G>A p.M524I | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as COSV52007321, COSV52031170; called by muse, mutect2, varscan2
- NLRP13 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV61620393; called by muse, mutect2, varscan2
- NLRP13 | c.1762T>G p.F588V | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV61620398; called by muse, mutect2, varscan2
- NLRP13 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs774572718, COSV61620402; called by muse, mutect2, varscan2
- NLRP4 | c.2077C>T p.Q693* | Nonsense Mutation (SNP) | VAF 32/122 reads (26%) | catalogued as COSV56709149; called by muse, mutect2, varscan2
- NLRP8 | c.3139A>G p.N1047D | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV52584196; called by muse, mutect2, varscan2
- NPAS3 | c.1953G>C p.E651D (on ENST00000356141 / NM_001164749.2; = p.E619D on NM_022123.3) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV60823946; called by muse, mutect2, varscan2
- NR5A2 | c.1009G>A p.E337K (on ENST00000367362 / NM_205860.3; = p.E291K on NM_003822.5) | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as rs368332488; called by muse, mutect2, varscan2
- NSD1 | c.7007T>G p.V2336G | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV61771757; called by muse, mutect2, varscan2
- NTPCR | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs759051611, COSV64052222; called by muse, mutect2, varscan2
- NTRK1 | c.356G>C p.R119P | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV62323927, COSV62324879; called by muse, mutect2, varscan2
- NUCB2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as COSV60374159; called by muse, mutect2, varscan2
- NUP210L | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55142893; called by muse, mutect2, varscan2
- NWD1 | c.2252G>A p.G751D | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV60338470; called by muse, mutect2, varscan2
- NWD1 | c.3095G>A p.G1032E | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs866682805, COSV60338490; called by muse, mutect2, varscan2
- OASL | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1311022496, COSV57477557; called by muse, mutect2, varscan2
- OBSCN | c.3724G>A p.G1242S | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as rs1294331835, COSV52736001, COSV52747824; called by muse, mutect2, varscan2
- OGDHL | c.2591G>A p.G864E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.594); catalogued as COSV65101307; called by muse, mutect2, varscan2
- OGDHL | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as rs372225129; called by muse, mutect2, varscan2
- OLFM3 | c.223A>T p.N75Y (on ENST00000338858 / NM_001288821.1; = p.N55Y on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1407022130, COSV58796307; called by muse, varscan2
- OMG | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55987754; called by muse, mutect2, varscan2
- OOEP | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.444); catalogued as COSV64859039; called by muse, mutect2, varscan2
- OR10K1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs746569386, COSV56870742, COSV99193195; called by muse, mutect2, varscan2
- OR10P1 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV59006786; called by muse, mutect2, varscan2
- OR11H6 | c.945G>A p.M315I | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV59643842; called by muse, mutect2, varscan2
- OR14J1 | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV65845536; called by muse, mutect2, varscan2
- OR14K1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs764245420, COSV99315001; called by muse, mutect2, varscan2
- OR14K1 | c.934A>T p.M312L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99315004; called by muse, mutect2, varscan2
- OR1B1 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs746183567, COSV59171296; called by muse, mutect2, varscan2
- OR1C1 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV68715462; called by muse, mutect2, varscan2
- OR1C1 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV101376218, COSV68715464; called by muse, mutect2, varscan2
- OR1D2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV58921162; called by muse, mutect2, varscan2
- OR2A12 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs769397640, COSV68821096; called by muse, varscan2
- OR2A2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/95 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV68871024; called by muse, mutect2, varscan2
- OR2A5 | c.275T>A p.I92N | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68738549; called by muse, mutect2, varscan2
- OR2AG1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56625563; called by muse, mutect2, varscan2
- OR2T11 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58184896; called by muse, mutect2, varscan2
- OR2W1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1226192074, COSV65851432, COSV65851562, COSV65852021; called by muse, mutect2, varscan2
- OR3A1 | c.363G>T p.M121I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60162626; called by muse, mutect2, varscan2
- OR4K17 | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV59647441; called by muse, mutect2, varscan2
- OR51B4 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.334); catalogued as COSV66516908; called by muse, mutect2, varscan2
- OR51Q1 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56178057; called by muse, mutect2, varscan2
- OR52L1 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs778527002, COSV59985989; called by muse, mutect2, varscan2
- OR6C68 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.532); catalogued as COSV65562858, COSV65563076; called by muse, mutect2, varscan2
- OR6S1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57837661; called by muse, mutect2, varscan2
- OR8G1 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV58380026, COSV58380659; called by muse, mutect2, varscan2
- OR9A2 | c.460T>G p.W154G | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.43); PolyPhen probably damaging (1); catalogued as COSV63306360; called by muse, mutect2, varscan2
- OSGEPL1 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV51461926, COSV51462182; called by muse, mutect2, varscan2
- OTOGL | c.980T>G p.F327C (on ENST00000547103; = p.F318C on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV72005872; called by muse, mutect2, varscan2
- OTOGL | c.3818C>T p.S1273F (on ENST00000547103; = p.S1264F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72005875; called by muse, mutect2, varscan2
- OTOGL | c.6922G>A p.E2308K (on ENST00000547103; = p.E2299K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV54013937; called by muse, mutect2, varscan2
- OVOL2 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1419305548, COSV53859667, COSV53861786; called by muse, mutect2, varscan2
- PALLD | c.3268G>A p.G1090R (on ENST00000505667 / NM_001166108.2; = p.G1073R on NM_016081.4) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV54974588; called by muse, mutect2, varscan2
- PAPPA2 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as COSV62774287; called by muse, mutect2, varscan2
- PAQR9 | c.851T>A p.L284Q | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV61417698; called by muse, mutect2, varscan2
- PARD6A | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.121); catalogued as COSV54666247; called by muse, varscan2
- PARD6B | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65404134, COSV65404327; called by muse, mutect2, varscan2
- PAX9 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.379); catalogued as COSV100825714; called by muse, mutect2, varscan2
- PCCA | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV66188779; called by muse, mutect2, varscan2
- PCDH15 | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.063); catalogued as COSV57269929; called by muse, varscan2
- PCDH15 | c.4241G>A p.R1414Q | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs866920137, COSV57268337; called by muse, mutect2, varscan2
- PCDH17 | c.3323G>A p.S1108N | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.954); catalogued as COSV64972281; called by muse, varscan2
- PCDH18 | c.2918C>T p.P973L | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV61266756, COSV61268802; called by muse, mutect2, varscan2
- PCDHA1 | c.1805G>A p.G602D | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65372929; called by muse, mutect2, varscan2
- PCDHA11 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV56481975; called by muse, mutect2, varscan2
- PCDHA13 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.295); catalogued as COSV56474354; called by muse, mutect2, varscan2
- PCDHA13 | c.2036C>T p.S679L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1562802468, COSV56481996; called by muse, mutect2, varscan2
- PCDHA2 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); catalogued as rs782787763, COSV65365287; called by muse, mutect2, varscan2
- PCDHA2 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.045); catalogued as COSV65365296; called by muse, mutect2, varscan2
- PCDHA8 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65335143; called by muse, mutect2, varscan2
- PCDHAC2 | c.2191T>G p.C731G | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV53839209, COSV99153530; called by muse, mutect2, varscan2
- PCDHB12 | c.171T>G p.S57R | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV53393764; called by muse, mutect2, varscan2
- PCDHB16 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53358709, COSV99502359; called by muse, mutect2, varscan2
- PCDHB4 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554274440, COSV52020064; called by muse, mutect2, varscan2
- PCDHB6 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs782536394, COSV50690800; called by muse, mutect2, varscan2
- PCDHGA4 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV53909235, COSV99038467; called by muse, mutect2, varscan2
- PCDHGA9 | c.2399C>T p.P800L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV53909260; called by muse, mutect2, varscan2
- PCLO | c.12049G>A p.E4017K | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749292764, COSV61619659, COSV61657525; called by muse, mutect2, varscan2
- PCLO | c.10754C>T p.S3585F | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61619672; called by muse, mutect2, varscan2
- PCLO | c.7322A>T p.K2441I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as COSV61619687; called by muse, mutect2
- PCLO | c.3361G>A p.D1121N | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV61619702, COSV61626832; called by muse, mutect2, varscan2
- PCNX4 | c.3517T>C p.*1173Qext*4 (on ENST00000406854 / NM_001330177.2; = p.*939Qext*4 on NM_022495.5) | Nonstop Mutation (SNP) | VAF 39/160 reads (24%) | catalogued as COSV58302648; called by muse, mutect2, varscan2
- PDE4DIP | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs782271941, COSV57674820; called by muse, mutect2, varscan2
- PDE6C | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777275171, COSV63271135; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDGFC | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs751613380, COSV56845738; called by muse, mutect2, varscan2
- PDIA3 | c.1494G>C p.K498N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.254); catalogued as COSV55854967; called by mutect2, varscan2
- PDYN | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV54101051; called by muse, mutect2, varscan2
- PDZD9 | c.691G>A p.E231K (on ENST00000424898 / NM_001363519.1; = p.E171K on NM_173806.4) | Missense Mutation (SNP) | VAF 82/354 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV51671065, COSV99193411; called by muse, mutect2, varscan2
- PFAS | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58978782; called by muse, mutect2, varscan2
- PGS1 | c.742C>A p.R248S | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53143732; called by muse, mutect2, varscan2
- PHF12 | c.1570T>A p.S524T | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.099); catalogued as COSV52018391; called by muse, mutect2, varscan2
- PI15 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as COSV52640013, COSV52643453; called by muse, mutect2, varscan2
- PI4K2B | c.1091G>A p.W364* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV53510489; called by muse, mutect2, varscan2
- PIK3R1 | c.1636G>C p.E546Q (on ENST00000521381 / NM_181523.3; = p.E276Q on NM_181504.4) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57125309, COSV57130430; called by muse, mutect2, varscan2
- PIWIL4 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as rs766849717, COSV54408087; called by muse, mutect2, varscan2
- PKDREJ | c.2104G>A p.D702N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV53547009; called by muse, mutect2, varscan2
- PKHD1 | c.2297G>A p.G766E | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as rs757772524, COSV61863595; called by muse, mutect2, varscan2
- PKHD1 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV61863609; called by muse, mutect2, varscan2
- PKHD1L1 | c.8273C>T p.S2758F | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV101006634, COSV65738685; called by muse, mutect2, varscan2
- PKN1 | c.1048G>A p.G350R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as rs1237932410, COSV54395259; called by muse, mutect2, varscan2
- PLA2R1 | c.3647G>A p.G1216E | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51775081; called by muse, mutect2, varscan2
- PLA2R1 | c.3272G>A p.G1091D | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.516); catalogued as rs778997231, COSV51775644; called by muse, mutect2, varscan2
- PLCB1 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.227); catalogued as COSV62040909; called by muse, mutect2, varscan2
- PLCB2 | c.3406G>A p.A1136T | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1189731632, COSV53031249; called by muse, mutect2, varscan2
- PLD2 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs267604956, COSV54004044; called by muse, mutect2, varscan2
- PLXDC1 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as COSV59549749; called by muse, mutect2, varscan2
- PLXDC2 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65901418; called by muse, mutect2, varscan2
- PLXDC2 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV65901422; called by muse, mutect2, varscan2
- PLXNA2 | c.4604C>T p.A1535V | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs566013352, COSV65438255; called by muse, mutect2, varscan2
- PLXNB1 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs1263861827, COSV56487272; called by muse, mutect2, varscan2
- PODXL | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.361); catalogued as rs753163466, COSV59868880; called by muse, mutect2
- POLA2 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as rs770313496, COSV55481177; called by muse, mutect2, varscan2
- POLR3H | c.112-1G>T p.X38_splice | Splice Site (SNP) | VAF 17/93 reads (18%) | catalogued as COSV61749272; called by muse, mutect2, varscan2
- PPP1R16B | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.837); catalogued as COSV55374792; called by muse, mutect2, varscan2
- PPP1R3A | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV52877787; called by muse, mutect2, varscan2
- PRF1 | c.1361G>A p.W454* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as CM080513, COSV64614486; called by muse, mutect2, varscan2
- PRG4 | c.3617G>A p.G1206E | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63355048; called by muse, mutect2, varscan2
- PRPF8 | c.5603T>G p.M1868R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59261221; called by muse, mutect2, varscan2
- PRSS55 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV60807869; called by muse, mutect2, varscan2
- PRTG | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as rs763021896, COSV66837007; called by muse, mutect2, varscan2
- PRTG | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66837010; called by muse, varscan2
- PSG1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 138/488 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs1058692; called by muse, mutect2, varscan2
- PSG2 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 107/385 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as rs1157626344, COSV61544688; called by muse, mutect2, varscan2
- PSG6 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 126/395 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV51830662, COSV99413742; called by muse, mutect2, varscan2
- PSMA8 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57601319; called by muse, mutect2, varscan2
- PTCHD1 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65059247; called by muse, mutect2, varscan2
- PTPRH | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54743181; called by muse, mutect2, varscan2
- PTPRJ | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1352567280, COSV69250176; called by muse, mutect2, varscan2
- PTPRK | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100949476, COSV63887216; called by muse, mutect2, varscan2
- PTPRZ1 | c.2165A>G p.E722G | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV66431709; called by muse, mutect2, varscan2
- RAB3IP | c.1139G>A p.R380Q (on ENST00000550536 / NM_175623.4; = p.R364Q on NM_022456.5) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as rs763536941, COSV56082133; called by muse, mutect2, varscan2
- RAB40B | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as rs202136186, COSV53915211; called by muse, mutect2, varscan2
- RAD54L2 | c.2572C>T p.P858S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs759617021, COSV56577337; called by muse, mutect2, varscan2
- RAI1 | c.3496G>A p.G1166S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55390051; called by muse, mutect2, varscan2
- RAN | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 29/115 reads (25%) | catalogued as COSV54562233; called by muse, mutect2, varscan2
- RANBP17 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV101206128; called by muse, mutect2, varscan2
- RANBP17 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66646307; called by muse, mutect2, varscan2
- RAP1GAP2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as rs775727034, COSV54572638; called by muse, mutect2, varscan2
- RAPGEF2 | c.809T>C p.I270T | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52425481; called by muse, mutect2, varscan2
- RASA3 | c.1706C>A p.P569H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV61864480; called by muse, mutect2
- RBBP4 | c.143A>G p.Q48R | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59384659; called by muse, mutect2, varscan2
- RBM15 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV63923147; called by muse, mutect2, varscan2
- RBMX | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV57807537; called by muse, mutect2, varscan2
- RC3H1 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51198196; called by muse, mutect2, varscan2
- RECK | c.551A>G p.E184G | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.169); catalogued as COSV65034783; called by muse, mutect2, varscan2
- REG1B | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100521570, COSV59304705; called by muse, mutect2, varscan2
- RFX7 | c.1910C>T p.S637F (on ENST00000559447 / NM_001368074.1; = p.S734F on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as COSV57960431, COSV57962944; called by muse, mutect2, varscan2
- RGS6 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs745879240, COSV59566797, COSV59588304; called by muse, mutect2, varscan2
- RIMBP2 | c.641-1G>A p.X214_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV55466586; called by muse, mutect2
- RIMS1 | c.2872C>T p.R958C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747771359, COSV53442594; called by muse, mutect2, varscan2
- RIMS1 | c.4988C>T p.S1663L | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53442613; called by muse, mutect2
- RIMS3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV65503990; called by muse, mutect2, varscan2
- RNF133 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV57351962; called by muse, mutect2, varscan2
- RNF133 | c.490T>A p.F164I | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV57351970; called by muse, mutect2, varscan2
- RNF144A | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV57980948; called by muse, mutect2, varscan2
- RP1 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as COSV55111640; called by muse, mutect2, varscan2
- RP1 | c.2992G>A p.D998N | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs777757393, COSV55111652; called by muse, mutect2, varscan2
- RP1 | c.4045G>A p.E1349K | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV55111661, COSV55113745; called by muse, mutect2, varscan2
- RP1L1 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV101223468, COSV101223690, COSV66752498; called by muse, mutect2, varscan2
- RPH3A | c.1474G>A p.E492K (on ENST00000389385 / NM_001143854.2; = p.E488K on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV66990190; called by muse, mutect2
- RPS5 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52190491; called by muse, mutect2, varscan2
- RPS6KA6 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53116940; called by muse, mutect2
- RPTN | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 619/1468 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV60166549; called by muse, mutect2, varscan2
- RSL1D1 | c.299A>G p.K100R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.739); catalogued as COSV63077480; called by muse, mutect2, varscan2
- RTL1 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV66016480; called by muse, mutect2, varscan2
- RTL10 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.076); catalogued as rs778185300, COSV100144292, COSV60735444; called by muse, mutect2, varscan2
- S1PR1 | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59512616; called by muse, mutect2, varscan2
- SAMD9 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs780430573, COSV66073396; called by muse, mutect2, varscan2
- SCG5 | c.622G>A p.D208N (on ENST00000300175 / NM_001144757.2; = p.D207N on NM_003020.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV55705366; called by muse, mutect2, varscan2
- SCMH1 | c.1946C>T p.S649F (on ENST00000326197 / NM_001031694.2; = p.S580F on NM_012236.4) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV58232888; called by muse, mutect2, varscan2
- SCN2A | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51834122; called by muse, mutect2, varscan2
- SCN2A | c.1880A>C p.Q627P | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); catalogued as COSV51834144; called by muse, mutect2, varscan2
- SCN4A | c.4672G>A p.E1558K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.524); catalogued as COSV71125818; called by muse, mutect2, varscan2
- SCN8A | c.2693G>A p.G898E | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61977451; called by muse, mutect2, varscan2
- SCNN1G | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55597482; called by muse, mutect2, varscan2
- SEC16B | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs762052922, COSV57623882; called by muse, mutect2, varscan2
- SEC23A | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as rs942298286, COSV56971562; called by muse, mutect2, varscan2
- SEMA3A | c.2276G>A p.R759K | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.562); catalogued as COSV54863341; called by muse, mutect2, varscan2
- SEMA3A | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.934); catalogued as rs762612767, COSV54863349; called by muse, mutect2, varscan2
- SEMG1 | c.330A>T p.K110N | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV99725113; called by muse, mutect2, varscan2
- SEMG1 | c.1211A>T p.K404I | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV99725117; called by muse, mutect2, varscan2
- SEMG1 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as COSV99725120; called by muse, mutect2, varscan2
- SEMG2 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.355); catalogued as COSV65647261; called by muse, mutect2, varscan2
- SERPINA3 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.746); catalogued as COSV67585408; called by muse, mutect2, varscan2
- SERPINB13 | c.851A>C p.H284P | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV54027598; called by muse, mutect2, varscan2
- SERPINB7 | c.645T>A p.N215K | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV60532818, COSV60536529; called by muse, mutect2, varscan2
- SERPINB7 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV60532822; called by muse, mutect2, varscan2
- SERPINC1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.08); catalogued as CM113644, COSV62928951; called by muse, mutect2
- SERPINI1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as rs1360805408, COSV55508418; called by muse, mutect2, varscan2
- SETD1A | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770463920, COSV52685514; called by muse, mutect2, varscan2
- SETD5 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56708201; called by muse, mutect2, varscan2
- SEZ6L2 | c.1259C>T p.S420L (on ENST00000308713 / NM_001114099.3; = p.S350L on NM_012410.4) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs1401372030, COSV58097614; called by muse, mutect2, varscan2
- SFMBT1 | c.1438C>T p.H480Y | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56252303; called by muse, mutect2, varscan2
- SGCZ | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.087); catalogued as rs149935102; called by muse, mutect2, varscan2
- SH3TC2 | c.53-2A>T p.X18_splice | Splice Site (SNP) | VAF 32/132 reads (24%) | catalogued as COSV60461359; called by muse, mutect2, varscan2
- SI | c.2555C>T p.S852L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV52268542; called by muse, mutect2
- SIM2 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51766502; called by muse, mutect2, varscan2
- SKAP1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV61144597; called by muse, mutect2, varscan2
- SLAMF6 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV63586527; called by muse, mutect2, varscan2
- SLC11A2 | c.536G>C p.W179S (on ENST00000394904 / NM_001379455.1; = p.W150S on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50369822, COSV50370471; called by muse, mutect2, varscan2
- SLC12A3 | c.2129C>T p.S710L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs546999572, CM040489, COSV52632933, COSV99344062; called by muse, mutect2, varscan2
- SLC12A3 | c.2431G>A p.A811T (on ENST00000563236 / NM_001126108.2; = p.A820T on NM_000339.3) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52632944; called by muse, mutect2, varscan2
- SLC12A8 | c.1850C>T p.T617I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV58863580; called by muse, mutect2, varscan2
- SLC13A1 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV52012668; called by mutect2, varscan2
- SLC22A3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51710697; called by muse, mutect2, varscan2
- SLC30A3 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV51984225; called by muse, mutect2, varscan2
- SLC35B3 | c.637T>C p.F213L | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59467479; called by muse, mutect2, varscan2
- SLC37A1 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs992141802, COSV61401510; called by muse, mutect2, varscan2
- SLC38A4 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56964769; called by muse, mutect2, varscan2
- SLC39A2 | c.682A>T p.I228L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.112); catalogued as COSV100068490; called by muse, mutect2, varscan2
- SLC39A2 | c.683T>A p.I228K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100068492; called by muse, mutect2, varscan2
- SLC3A1 | c.1856G>A p.R619K | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV53215395; called by muse, mutect2
- SLC40A1 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as COSV53722092; called by muse, mutect2, varscan2
- SLC4A1 | c.2697A>C p.E899D | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52258715; called by muse, mutect2, varscan2
- SLC4A1 | c.42G>T p.E14D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV52258726; called by muse, mutect2, varscan2
- SLC4A5 | c.1480T>C p.F494L | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0.2); catalogued as COSV61025179; called by muse, mutect2, varscan2
- SLC5A7 | c.669A>T p.K223N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.18); catalogued as COSV50889299; called by muse, mutect2, varscan2
- SLC5A7 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50889314; called by muse, mutect2, varscan2
- SLC5A8 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867168951, COSV101610512, COSV73310407; called by muse, mutect2, varscan2
- SLC5A8 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as rs774392367, COSV73310408; called by muse, mutect2, varscan2
- SLC6A1 | c.836T>G p.L279R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV55113592; called by muse, mutect2, varscan2
- SLC6A11 | c.1514G>A p.G505D | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54390567; called by muse, mutect2, varscan2
- SLC9A1 | c.805G>C p.V269L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV56051607; called by muse, mutect2, varscan2
- SLCO1B1 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57007965; called by muse, mutect2, varscan2
- SLCO4C1 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.102); catalogued as rs145667218; called by muse, mutect2, varscan2
- SLFN11 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV57697818; called by muse, mutect2, varscan2
- SLFN13 | c.161T>C p.L54S | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53192460; called by muse, mutect2, varscan2
- SLITRK1 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV65674545; called by muse, mutect2, varscan2
- SLITRK6 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV68389529; called by muse, mutect2, varscan2
- SMPD3 | c.1504G>A p.V502M | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54710752; called by muse, mutect2, varscan2
- SMR3A | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.444); catalogued as rs941824308, COSV56949852; called by muse, varscan2
- SMYD3 | c.302C>T p.S101F (on ENST00000490107 / NM_001375962.1; = p.S42F on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV66436712; called by muse, mutect2, varscan2
- SNED1 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs755479039, COSV60020164; called by muse, mutect2, varscan2
- SNRK | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV56066342; called by muse, mutect2, varscan2
- SNX9 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV67583403; called by muse, mutect2, varscan2
- SOX6 | c.2416G>T p.D806Y (on ENST00000528429 / NM_001145819.2; = p.D779Y on NM_017508.3) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV57038844; called by muse, mutect2, varscan2
- SP140 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59446871; called by muse, mutect2, varscan2
- SPAG16 | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV55983710, COSV55985202; called by muse, mutect2, varscan2
- SPAG5 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.012); catalogued as COSV58800358; called by muse, mutect2, varscan2
- SPATA45 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 101/200 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60571469; called by muse, mutect2, varscan2
- SPECC1L | c.2798C>A p.P933H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV58656886; called by muse, mutect2, varscan2
- SPSB4 | c.719T>G p.L240R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60145583; called by mutect2, varscan2
- SPTB | c.4007G>A p.G1336E | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67630215; called by muse, mutect2, varscan2
- SPTB | c.172A>T p.K58* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as COSV67630218; called by muse, mutect2, varscan2
- SSBP3 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62573013; called by muse, mutect2, varscan2
- STAU1 | c.448C>T p.H150Y (on ENST00000371856 / NM_001319135.1; = p.H69Y on NM_004602.3) | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV61459239; called by muse, mutect2, varscan2
- STIP1 | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.676); catalogued as COSV99656369; called by muse, mutect2, varscan2
- STK31 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV63454463; called by muse, mutect2, varscan2
- STRIP2 | c.1988C>T p.S663F | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50803445; called by muse, mutect2, varscan2
- STX2 | c.678T>G p.G226= | Splice Region (SNP) | VAF 20/88 reads (23%) | catalogued as COSV55432267; called by muse, mutect2, varscan2
- STYK1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV50012508; called by muse, mutect2, varscan2
- SULT1E1 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV56946307; called by muse, mutect2, varscan2
- SULT2A1 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55764288; called by muse, mutect2, varscan2
- SUSD4 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV59550336; called by muse, mutect2, varscan2
- SUV39H2 | c.625C>T p.L209F (on ENST00000354919 / NM_001193424.2; = p.L149F on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV57953008, COSV57954802; called by muse, mutect2, varscan2
- SVEP1 | c.8411G>A p.G2804E | Missense Mutation (SNP) | VAF 80/145 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52836433; called by muse, mutect2, varscan2
- SVEP1 | c.4007G>A p.G1336E | Missense Mutation (SNP) | VAF 132/270 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57028573; called by muse, mutect2, varscan2
- SVIL | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV63440692; called by muse, mutect2
- SYCP2L | c.1119G>A p.M373I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51650520; called by muse, mutect2, varscan2
- SYNE2 | c.3626C>T p.T1209I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1436405196, COSV59941715; called by muse, mutect2, varscan2
- SYNJ1 | c.3859C>T p.P1287S | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.046); catalogued as rs866085400, COSV59145074; called by muse, mutect2, varscan2
- SYNPO | c.1868C>T p.S623F (on ENST00000394243 / NM_001166208.2; = p.S379F on NM_007286.6) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56938835; called by muse, mutect2, varscan2
- SYT2 | c.593A>G p.K198R | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV66141355; called by muse, mutect2, varscan2
- SZT2 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1262826738, COSV65167794; called by muse, mutect2, varscan2
- TACC2 | c.6466G>A p.E2156K (on ENST00000334433; = p.E234K on NM_006997.4) | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV53277140; called by muse, mutect2, varscan2
- TAF4 | c.3107C>T p.S1036L | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs941802918, COSV53334442; called by muse, mutect2, varscan2
- TAFA4 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs752453217, COSV55134452; called by muse, mutect2, varscan2
- TAOK3 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as rs1162571974, COSV66824923; called by muse, mutect2, varscan2
- TAS2R16 | c.313A>C p.I105L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV50796856; called by muse, mutect2, varscan2
- TBC1D8 | c.1471T>A p.C491S | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV100964310; called by muse, mutect2, varscan2
- TCHHL1 | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 54/289 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as COSV64285034; called by muse, mutect2, varscan2
- TCN2 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs777103002, COSV53190795; called by muse, mutect2, varscan2
- TCTN2 | c.578A>C p.N193T | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV57631788; called by muse, mutect2, varscan2
- TDRKH | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1004423330, COSV64316048; called by muse, mutect2, varscan2
- TEKT1 | c.362A>C p.K121T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV100106016; called by muse, mutect2, varscan2
- TENM4 | c.6884G>A p.G2295D | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV53612545; called by muse, mutect2, varscan2
- TENT4A | c.1646A>C p.K549T | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.572); catalogued as rs1422064584, COSV50094562; called by muse, mutect2, varscan2
- TET1 | c.2897A>T p.N966I | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV101017747; called by muse, mutect2, varscan2
- TEX15 | c.7315A>T p.N2439Y (on ENST00000256246; = p.N2822Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.41); catalogued as COSV56342602; called by muse, mutect2, varscan2
- TG | c.5411C>T p.P1804L | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1291041050, COSV55067147; called by muse, mutect2, varscan2
- TGFBI | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV59350182; called by muse, mutect2, varscan2
- TGM7 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV71772603; called by muse, mutect2, varscan2
- THBS1 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.037); catalogued as COSV52950444; called by muse, mutect2, varscan2
- THPO | c.577G>A p.V193I (on ENST00000649095 / NM_001290003.1; = p.V53I on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1195404124, COSV52605959; called by muse, varscan2
- THSD7B | c.1588C>T p.H530Y | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55660924; called by muse, mutect2, varscan2
- THSD7B | c.3370C>A p.L1124I (on ENST00000272643; = p.L1122I on NM_001316349.2) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV55660947, COSV55738089; called by muse, mutect2, varscan2
- THSD7B | c.3538G>A p.E1180K (on ENST00000272643; = p.E1178K on NM_001316349.2) | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.699); catalogued as COSV55655747, COSV99742785; called by muse, mutect2, varscan2
- TIE1 | c.1760G>A p.G587E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.258); catalogued as rs1490777491, COSV65248771; called by muse, mutect2, varscan2
- TMCC3 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs781764514, COSV54152619, COSV54153235; called by muse, mutect2, varscan2
- TMCO4 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs142352343, COSV53872151; called by muse, mutect2, varscan2
- TMEM132B | c.2830G>A p.D944N | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774667643, COSV54746669; called by muse, mutect2, varscan2
- TMEM132D | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.941); catalogued as COSV67158993; called by muse, mutect2, varscan2
- TMEM132D | c.2449C>T p.H817Y | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV67158999; called by muse, mutect2, varscan2
- TMEM259 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as rs762061182, COSV52258926; called by muse, mutect2, varscan2
- TMEM43 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs762333890, COSV60145444; called by muse, mutect2, varscan2
- TMEM67 | c.313-1G>A p.X105_splice | Splice Site (SNP) | VAF 24/75 reads (32%) | catalogued as COSV60036629; called by muse, mutect2, varscan2
556 further variants in this file (125 protein-altering or splice-affecting, 405 silent, 26 other) are not listed here.
